Gene-level copy-number profile of tumor specimen TCGA-OR-A5LT-01A from TCGA case TCGA-OR-A5LT, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 57.6 years (21,032 days).
Specimen TCGA-OR-A5LT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.55359604-76a7-43a3-b621-09ca64d547d2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5LT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3eac0a01-1d58-4fe1-a611-88ebb17f3a19

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 209; copy number 2: 32,463; copy number 3: 9,905; copy number 4: 15,152; copy number 5: 297; copy number 6: 1,009; copy number 7: 91; copy number 8: 106; copy number 9: 454; copy number 10: 68; copy number 11: 63; copy number 12: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5LT-01A-11D-A29H-01): tumor purity 0.92, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,089 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–60,796,103, 891 genes, copy number 5–6 (broad region; genes not listed).
- chr5:710,355–1,295,068, 20 genes, copy number 9 (within-gene range 4–9): ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr5:2,831,021–2,967,955, 2 genes, copy number 6: AC094105.1, AC094105.2.
- chr5:10,225,507–10,249,897, 1 gene, copy number 12 (within-gene range 4–12): ATPSCKMT.
- chr5:13,553,654–13,553,966, 1 gene, copy number 7: NENFP3.
- chr5:14,356,886–19,234,487, 98 genes, copy number 10–11 (broad region; genes not listed).
- chr5:20,611,806–21,196,860, 4 genes, copy number 10 (within-gene range 4–10): LINC02241, AC138938.1, AC140168.1, AC140172.1.
- chr5:24,772,144–25,445,925, 14 genes, copy number 7: AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2.
- chr5:26,382,519–63,571,617, 493 genes, copy number 7–9 (broad region; genes not listed).
- chr20:49,503,874–55,075,140, 96 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr21:13,909,574–13,980,437, 1 gene, copy number 6 (within-gene range 3–6): ANKRD20A11P.
- chr21:13,968,489–18,267,373, 75 genes, copy number 6 (broad region; genes not listed).
- chr21:18,561,265–21,797,415, 32 genes, copy number 6–11 (within-gene range 3–11): MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425.
- chr21:23,704,260–36,419,015, 265 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr21:43,529,186–44,711,572, 72 genes, copy number 5 (broad region; genes not listed).
- chr21:44,978,832–45,379,635, 16 genes, copy number 8: AP001505.1, LINC00163, LINC00165, PICSAR, SSR4P1, ADARB1, AL133499.1, LINC00334, POFUT2, LINC00205, BX322557.2, LINC00315, BX322557.1, LINC00316, MTCO1P3, BX322559.1.
- chr21:45,643,694–45,942,454, 5 genes, copy number 7 (within-gene range 1–7): PCBP3, AL133492.1, PCBP3-AS1, AJ011931.2, AJ011931.1.
- chr21:46,598,604–46,665,124, 3 genes, copy number 7: S100B, PRMT2, DSTNP1.

Autosomal genes at a single copy (total copy number 1): 209. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
